Somatic mutation profile of tumor specimen TCGA-DD-AADR-01A (aliquot TCGA-DD-AADR-01A-11D-A40R-10) from TCGA case TCGA-DD-AADR, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 58.1 years (21,217 days).
Specimen TCGA-DD-AADR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac582f8c-ab8f-4c35-b13d-37aaf2d89d2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADR-10A (Blood Derived Normal), aliquot TCGA-DD-AADR-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/620a91b8-4e36-424a-b50b-59c727eaa0c5

The open-access MAF lists 106 somatic variants for this specimen: 79 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Nonsense Mutation 8, Frame Shift Del 4, Splice Site 2, Intron 2, In Frame Del 2, Frame Shift Ins 2, 3'UTR 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 63/199 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCE1 | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99668474; called by muse, mutect2, varscan2
- ABI2 | c.1185G>C p.Q395H (on ENST00000295851 / NM_001375719.1; = p.Q328H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53696633, COSV99651623; called by muse, mutect2, varscan2
- AGFG2 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99499227; called by muse, mutect2, varscan2
- AL645922.1 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV100190904; called by muse, mutect2, varscan2
- ALPI | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763287848, COSV99785763; called by muse, mutect2, varscan2
- AMPD1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs149424604, COSV100814939; called by muse, mutect2, varscan2
- ASF1A | c.556T>C p.W186R | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.093); catalogued as COSV99995757; called by muse, mutect2, varscan2
- ATP2A2 | c.2071C>T p.Q691* | Nonsense Mutation (SNP) | VAF 35/129 reads (27%) | catalogued as COSV100428485; called by muse, mutect2, varscan2
- BARX2 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV99858463; called by muse, mutect2
- BNIP5 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as COSV101465126; called by muse, mutect2, varscan2
- CDC27 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 76/256 reads (30%) | catalogued as COSV99294254; called by muse, mutect2, varscan2
- CDH4 | c.926C>A p.T309K | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100848575, COSV64661310; called by muse, mutect2, varscan2
- COL18A1 | c.3432+1G>A p.X1144_splice (on ENST00000359759 / NM_130444.3; = p.X909_splice on NM_030582.4) | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100645079; called by muse, mutect2, varscan2
- CPOX | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV99939064; called by muse, mutect2, varscan2
- DLD | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226919; called by muse, mutect2, varscan2
- DLX5 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs762498461, COSV99756314; called by muse, mutect2, varscan2
- EFCAB12 | c.1052T>C p.I351T | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100394525; called by muse, mutect2, varscan2
- EFCC1 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101459966; called by muse, mutect2, varscan2
- ELP4 | c.824A>C p.N275T (on ENST00000350638; = p.N274T on NM_019040.5) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100635217; called by muse, mutect2, varscan2
- FAT4 | c.5923A>T p.I1975F | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV100627814; called by muse, mutect2
- FLG | c.7176T>A p.H2392Q | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.049); catalogued as rs1163393680, COSV100911241; called by muse, mutect2, varscan2
- FOXB2 | c.848T>A p.V283E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100942327; called by muse, mutect2, varscan2
- GIPC1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as COSV100600034, COSV61774133; called by muse, mutect2, varscan2
- GNPTG | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99201413; called by muse, mutect2, varscan2
- GRIN2C | c.1168T>C p.Y390H | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV99500734; called by muse, mutect2, varscan2
- GUCY2D | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs745426085, COSV99643843; called by muse, mutect2, varscan2
- HAUS1 | c.837A>G p.*279Wext*10 | Nonstop Mutation (SNP) | VAF 83/379 reads (22%) | catalogued as COSV99959391; called by muse, mutect2, varscan2
- HP1BP3 | c.1364G>C p.R455T | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV100391652, COSV56562892; called by muse, mutect2, varscan2
- IFITM3 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101296771; called by muse, mutect2, varscan2
- IGDCC4 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV100732770; called by muse, mutect2, varscan2
- IL17RC | c.2329C>T p.R777C (on ENST00000295981 / NM_153461.4; = p.R691C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99925628; called by muse, mutect2, varscan2
- JADE1 | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99885521; called by muse, mutect2, varscan2
- KCNH6 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 55/158 reads (35%) | catalogued as rs756075949, COSV100120886; called by muse, mutect2, varscan2
- KRBA1 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99752359; called by muse, mutect2, varscan2
- LDB2 | c.104T>C p.M35T | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV100453070; called by muse, mutect2, varscan2
- LDB3 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99554893; called by muse, mutect2, varscan2
- LYST | c.7353_7355del p.L2452del | In Frame Del (DEL) | VAF 105/349 reads (30%) | catalogued as rs765160019; called by pindel, varscan2
- MBP | c.470A>G p.H157R (on ENST00000355994 / NM_001025101.2; = p.H24R on NM_002385.3) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.824); catalogued as rs755800293, COSV100592532; called by muse, mutect2, varscan2
- MICAL3 | c.4845G>T p.R1615S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV101490836; called by muse, mutect2, varscan2
- MOGS | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1246940304, COSV99280873; called by muse, mutect2, varscan2
- MUC5B | c.15425C>A p.S5142Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101500150, COSV71594880; called by muse, mutect2, varscan2
- MYH1 | c.5507G>A p.R1836H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs376702386; called by muse, mutect2, varscan2
- NOTCH2 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99071857, COSV99863277; called by muse, mutect2, varscan2
- NRCAM | c.2877G>T p.K959N (on ENST00000379028 / NM_001371124.1; = p.K943N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV100694476; called by muse, mutect2, varscan2
- OSBPL11 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375600104; called by muse, mutect2, varscan2
- PCDHGB4 | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99533857; called by muse, mutect2, varscan2
- PDS5A | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 68/188 reads (36%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.771); catalogued as COSV100337243; called by muse, mutect2, varscan2
- PLCXD3 | c.226T>A p.W76R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100125456, COSV100125557; called by muse, mutect2, varscan2
- PNPLA5 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV99336543; called by muse, mutect2, varscan2
- POLQ | c.3436G>A p.V1146M | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as rs751919003, COSV51764315; called by muse, mutect2, varscan2
- PSMD1 | c.2405A>G p.Y802C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs761435030, COSV58083739; called by muse, mutect2, varscan2
- RBPMS | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV99823741; called by muse, mutect2, varscan2
- RGMA | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | catalogued as COSV100224243; called by muse, mutect2, varscan2
- RNF123 | c.3328C>T p.R1110C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764220503, COSV100246503; called by muse, mutect2, varscan2
- ROBO3 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184968, COSV67300071; called by muse, mutect2, varscan2
- SATB1 | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100113005; called by muse, mutect2, varscan2
- SERAC1 | c.1643A>G p.Y548C | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs781401323, COSV100894813; called by muse, mutect2, varscan2
- SIGLEC9 | c.1282del p.E428Kfs*14 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | catalogued as COSV51588264; called by mutect2, pindel, varscan2
- SP1 | c.410C>T p.S137F (on ENST00000327443 / NM_138473.3; = p.S130F on NM_003109.1) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV100540474; called by muse, mutect2, varscan2
- TARBP1 | c.3989G>A p.G1330E | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99241272; called by muse, mutect2, varscan2
- TBX18 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs781249482, COSV63737427; called by muse, mutect2, varscan2
- TF | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs752715864, COSV53923681; called by muse, mutect2, varscan2
- TLCD4 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100930747, COSV64632626; called by muse, mutect2, varscan2
- TRIM56 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs765379859, COSV60159245; called by muse, mutect2
- TROAP | c.2245G>C p.V749L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV99226722; called by muse, mutect2, varscan2
- TTLL7 | c.1290+2T>C p.X430_splice | Splice Site (SNP) | VAF 41/109 reads (38%) | catalogued as COSV99552106; called by muse, mutect2, varscan2
- WDR38 | c.870dup p.V291Sfs*9 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | catalogued as rs749634832; called by mutect2, pindel, varscan2
- ZCCHC3 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV101210846; called by muse, mutect2, varscan2
- ZNF135 | c.1496G>A p.C499Y (on ENST00000313434 / NM_001289401.2; = p.C511Y on NM_003436.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57882884; called by muse, mutect2, varscan2
- ZNF436 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100010969; called by muse, mutect2, varscan2
- ZNF441 | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV100777410; called by muse, mutect2, varscan2
- ARID1A | c.494del p.A165Gfs*67 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by mutect2, pindel, varscan2
- FAT1 | c.7A>T p.R3* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- FCGBP | c.9397G>A p.A3133T | Missense Mutation (SNP) | VAF 47/286 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- HARS2 | c.568del p.A190Qfs*4 | Frame Shift Del (DEL) | VAF 36/133 reads (27%) | called by mutect2, pindel, varscan2
- MED28 | c.59_67del p.P20_G22del | In Frame Del (DEL) | VAF 45/108 reads (42%) | called by mutect2, pindel, varscan2
- NHS | c.2880del p.E961Rfs*87 | Frame Shift Del (DEL) | VAF 86/146 reads (59%) | called by mutect2, pindel, varscan2
- SRRT | c.1448dup p.N484Efs*8 | Frame Shift Ins (INS) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- AQP9 | c.69G>A p.A23= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs370186994; called by muse, mutect2, varscan2
- BICRAL | c.444C>G p.S148= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV100017938, COSV58405171; called by muse, mutect2, varscan2
- C1orf226 | c.462A>G p.P154= | Silent (SNP) | VAF 69/182 reads (38%) | catalogued as COSV100908025; called by muse, mutect2, varscan2
- CCIN | c.150C>A p.S50= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as COSV100631767; called by muse, mutect2, varscan2
- CDH17 | c.1023G>A p.P341= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as rs765227677, COSV99217135; called by muse, mutect2
- DMXL2 | c.1002A>G p.L334= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as COSV99196109; called by muse, mutect2, varscan2
- DNAJA4 | c.841T>C p.L281= (on ENST00000343789; = p.L310= on NM_018602.3) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100655084, COSV100655151; called by muse, mutect2, varscan2
- IQSEC3 | c.1590C>A p.G530= (on ENST00000538872 / NM_001170738.2; = p.G227= on NM_015232.1) | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100406969, COSV58281451; called by muse, varscan2
- M1AP | c.340C>T p.L114= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as COSV99303868; called by muse, mutect2, varscan2
- MST1R | c.3175C>T p.L1059= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV99618159; called by muse, mutect2, varscan2
- NVL | c.2562C>T p.L854= | Silent (SNP) | VAF 95/340 reads (28%) | catalogued as rs1225499099, COSV99893891; called by muse, mutect2, varscan2
- PFDN5 | c.243C>T p.H81= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs1032639570, COSV99229045; called by muse, mutect2
- PTK2 | c.2181A>G p.E727= | Silent (SNP) | VAF 44/263 reads (17%) | catalogued as COSV100569808; called by muse, mutect2, varscan2
- RALYL | c.502A>C p.R168= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV101569098; called by muse, mutect2, varscan2
- SCN2A | c.1503G>T p.L501= | Silent (SNP) | VAF 52/154 reads (34%) | catalogued as COSV99330724; called by muse, mutect2, varscan2
- SLC6A12 | c.1575C>T p.Y525= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as rs1231446451, COSV100675021; called by muse, mutect2, varscan2
- THNSL1 | c.510A>T p.T170= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100896150; called by muse, mutect2
- TRPC3 | c.831G>A p.R277= (on ENST00000379645 / NM_001366479.2; = p.R204= on NM_003305.2) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV53376221; called by muse, mutect2
- TTN | c.46680G>T p.L15560= (on ENST00000591111; = p.L8136= on NM_003319.4) | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV100601339, COSV60162298; called by muse, mutect2, varscan2
- USP42 | c.1896G>A p.V632= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100084119; called by muse, mutect2, varscan2
- VPS13A | c.4065A>G p.Q1355= | Silent (SNP) | VAF 68/259 reads (26%) | catalogued as rs970555193, COSV100652377; called by muse, mutect2, varscan2
- ZNF474 | c.645C>T p.T215= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV99682064; called by muse, mutect2, varscan2
- ZNF507 | c.1933C>T p.L645= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV100321671; called by muse, mutect2, varscan2
- ANXA3 | c.*1A>G | 3'UTR (SNP) | VAF 36/75 reads (48%) | catalogued as COSV99363621; called by muse, mutect2, varscan2
- MBNL1 | c.1016-718A>G | Intron (SNP) | VAF 29/91 reads (32%) | catalogued as COSV99219900; called by muse, mutect2, varscan2
- OBSCN | c.11659+4451G>A | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99475209; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039521 G>A | 5'Flank (SNP) | VAF 9/57 reads (16%) | catalogued as rs763026787; called by muse, mutect2, varscan2
